Somatic mutation profile of tumor specimen TCGA-GD-A3OQ-01A (aliquot TCGA-GD-A3OQ-01A-32D-A21Z-08) from TCGA case TCGA-GD-A3OQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 48.4 years (17,682 days).
Specimen TCGA-GD-A3OQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d07208c-5a15-4f8c-b0ca-a10b69d10d63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GD-A3OQ-10A (Blood Derived Normal), aliquot TCGA-GD-A3OQ-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cb9ef12-c929-47d7-9d54-ab46c57d049c

The open-access MAF lists 109 somatic variants for this specimen: 89 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 16, Nonsense Mutation 6, Frame Shift Ins 4, Splice Region 2, Frame Shift Del 2, Intron 2, Splice Site 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 70/189 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 48/65 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54087081; called by muse, mutect2, varscan2
- ACTN4 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as COSV53143984; called by muse, mutect2, varscan2
- AFTPH | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 119/274 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV53216571; called by muse, mutect2, varscan2
- AGPAT3 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52368658, COSV99377224; called by muse, mutect2, varscan2
- AMPD1 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62415397, COSV62415673; called by muse, mutect2, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 127/394 reads (32%) | catalogued as rs1415146710; called by mutect2, pindel, varscan2
- CACNA1G | c.5992C>G p.L1998V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as COSV61721960, COSV61730956; called by muse, mutect2, varscan2
- CASD1 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV99802603; called by muse, mutect2, varscan2
- CDH4 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs749580573, COSV64645529; called by muse, mutect2, varscan2
- CDK12 | c.3986C>T p.S1329F (on ENST00000447079 / NM_016507.4; = p.S1320F on NM_015083.3) | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); catalogued as COSV70999743, COSV71001749; called by muse, mutect2, varscan2
- CDKN1A | c.182dup p.D62* | Frame Shift Ins (INS) | VAF 30/60 reads (50%) | catalogued as COSV99057425; called by mutect2, pindel, varscan2
- CELSR3 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV50841296, COSV50842619; called by muse, mutect2, varscan2
- CMIP | c.1323G>A p.M441I (on ENST00000537098 / NM_198390.2; = p.M347I on NM_030629.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV67697497; called by muse, mutect2, varscan2
- CRLF3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs373829171, COSV60835410; called by muse, mutect2, varscan2
- CXCL11 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.134); catalogued as COSV100134867, COSV60666200; called by muse, mutect2, varscan2
- CYP4F2 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV50000535; called by muse, mutect2, varscan2
- DAAM2 | c.3178G>A p.E1060K (on ENST00000274867 / NM_001201427.2; = p.E1059K on NM_015345.3) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51305211, COSV99227668; called by muse, mutect2, varscan2
- DEPDC5 | c.2762G>A p.R921Q (on ENST00000400246; = p.R990Q on NM_014662.5) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.646); catalogued as rs201245740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DKK3 | c.113T>A p.L38H | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); catalogued as COSV58868104; called by muse, mutect2, varscan2
- DMXL1 | c.3818C>T p.S1273F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV60707062; called by muse, mutect2
- EIF2B2 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV56719947; called by muse, mutect2, varscan2
- EP300 | c.4154G>A p.C1385Y | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54325300, COSV54328894; called by muse, mutect2, varscan2
- ERBIN | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52312697; called by muse, mutect2, varscan2
- ERCC2 | c.2272C>G p.Q758E | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV67267217; called by muse, mutect2, varscan2
- EVX1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV56084927; called by muse, mutect2, varscan2
- FBLN1 | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV53044853; called by muse, mutect2, varscan2
- FBXO28 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV64799504, COSV64799923; called by muse, mutect2
- FIP1L1 | c.228G>A p.P76= | Splice Region (SNP) | VAF 10/95 reads (11%) | catalogued as COSV60994684, COSV61000254; called by muse, mutect2, varscan2
- FIP1L1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60994703; called by muse, mutect2
- FLG | c.4604C>G p.S1535* | Nonsense Mutation (SNP) | VAF 52/480 reads (11%) | catalogued as rs1345660124; called by muse, mutect2, varscan2
- GDF2 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs782560993; called by muse, mutect2, varscan2
- GIGYF2 | c.3306-1G>A p.X1102_splice | Splice Site (SNP) | VAF 17/69 reads (25%) | catalogued as COSV65247527; called by muse, mutect2, varscan2
- GRM7 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV63134830; called by muse, mutect2, varscan2
- GUCY2F | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 59/78 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV54299699; called by muse, mutect2, varscan2
- HIC2 | c.949A>G p.S317G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV68041813; called by muse, mutect2
- INKA2 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs112881255, COSV61877343; called by muse, mutect2
- INPP5F | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62819888; called by muse, mutect2, varscan2
- ITSN2 | c.1417C>G p.Q473E | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV61944769; called by muse, mutect2
- KCNC1 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56392538; called by muse, mutect2, varscan2
- KCNQ4 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV61271838; called by muse, mutect2
- KIF20B | c.4151A>G p.Q1384R (on ENST00000371728 / NM_001284259.2; = p.Q1344R on NM_016195.4) | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1203448954, COSV53304263; called by muse, mutect2, varscan2
- LY75-CD302 | c.5519C>A p.S1840Y | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV52028075; called by muse, mutect2, varscan2
- LYSMD1 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1390276996, COSV64419958; called by muse, mutect2, varscan2
- MACF1 | c.8830C>G p.Q2944E | Missense Mutation (SNP) | VAF 10/115 reads (9%) | catalogued as COSV57111556; called by muse, mutect2
- MASP2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775120367, COSV68896171; called by muse, mutect2, varscan2
- MDC1 | c.4373C>G p.S1458C | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV64523674, COSV64523819; called by muse, mutect2, varscan2
- NUTM1 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs988931364, COSV59216088; called by muse, mutect2, varscan2
- NUTM1 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV59215842; called by muse, mutect2
- NXF3 | c.1182C>G p.F394L | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV67702992; called by muse, mutect2, varscan2
- OSBPL5 | c.138G>A p.G46= | Splice Region (SNP) | VAF 5/41 reads (12%) | catalogued as COSV55140265; called by muse, mutect2, varscan2
- PATJ | c.5377G>C p.E1793Q | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV64501893; called by muse, mutect2, varscan2
- PCDHB11 | c.1325C>G p.S442C | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV61309932; called by muse, mutect2, varscan2
- PCNX3 | c.5296C>T p.R1766C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63135518; called by muse, mutect2, varscan2
- PPP3CB | c.1132C>G p.L378V | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV61151319; called by muse, mutect2
- RAE1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64797921; called by muse, mutect2
- RELN | c.6317G>C p.R2106T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58991246; called by muse, mutect2, varscan2
- RYR2 | c.12647C>T p.A4216V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.36); catalogued as rs375950722; called by muse, mutect2, varscan2
- SCAMP4 | c.570G>C p.W190C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60190437; called by muse, mutect2
- SCN1A | c.5771G>T p.R1924L (on ENST00000303395 / NM_001202435.3; = p.R1913L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57663941, COSV57666596; called by muse, mutect2, varscan2
- SEMA5B | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs199707337, COSV52091312; called by muse, mutect2, varscan2
- SERPINH1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs755143041, COSV63997825; called by muse, mutect2, varscan2
- SF3B1 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59209855; called by muse, mutect2, varscan2
- SLC7A2 | c.1906C>T p.Q636* (on ENST00000494857 / NM_001370338.1; = p.Q675* on NM_003046.6) | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs930882332; called by muse, mutect2, varscan2
- SLC7A7 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV53536637; called by muse, mutect2, varscan2
- SLC9A3 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53799681, COSV53801717; called by muse, mutect2, varscan2
- SRD5A1 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV57013330, COSV57014523; called by muse, mutect2, varscan2
- THG1L | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as COSV51452481; called by muse, mutect2
- TNNI3K | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV53945412; called by muse, mutect2
- TOPORS | c.1282T>G p.S428A | Missense Mutation (SNP) | VAF 88/120 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV62116441; called by muse, mutect2, varscan2
- TRIM51 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV55264733; called by muse, mutect2, varscan2
- UBTD1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs369010339; called by muse, mutect2, varscan2
- UQCRC2 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV51671254; called by muse, mutect2, varscan2
- UROS | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.496); catalogued as COSV64229612; called by muse, mutect2
- VPS13C | c.5711G>C p.R1904T (on ENST00000644861 / NM_020821.3; = p.R1861T on NM_017684.5) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV51132152; called by muse, mutect2, varscan2
- WDR49 | c.896C>T p.T299M (on ENST00000308378 / NM_001366158.1; = p.T640M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200695837, COSV57704608; called by muse, mutect2, varscan2
- WDR7 | c.3347C>G p.S1116C | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV54349857, COSV54358123; called by muse, mutect2
- WTAP | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61609889; called by muse, mutect2, varscan2
- XRCC6 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs776773263, COSV63158525; called by muse, mutect2, varscan2
- ZNF786 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100303028; called by muse, mutect2, varscan2
- ZNHIT6 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs755555501, COSV65326781; called by muse, mutect2, varscan2
- AP2B1 | c.2141G>C p.W714S | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CCAR1 | c.2416dup p.S806Kfs*5 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- CDH8 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRBA | c.6883C>T p.Q2295* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- MCF2L | c.681del p.W227Cfs*15 (on ENST00000375608; = p.W195Cfs*15 on NM_024979.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- RREB1 | c.1390_1396del p.A464Sfs*9 | Frame Shift Del (DEL) | VAF 117/159 reads (74%) | called by mutect2, pindel, varscan2
- RUFY2 | c.50dup p.L17Ffs*6 | Frame Shift Ins (INS) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- ARF6 | c.441G>A p.R147= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV53597389; called by muse, mutect2, varscan2
- ARHGAP5 | c.3300A>G p.K1100= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV61534453; called by muse, mutect2, varscan2
- CHD5 | c.3600C>G p.L1200= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV52410172; called by muse, mutect2
- COL27A1 | c.2757C>T p.G919= | Silent (SNP) | VAF 75/103 reads (73%) | catalogued as rs558379555, COSV61923065; called by muse, mutect2, varscan2
- DHRS4 | c.825G>A p.P275= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100365779; called by mutect2, varscan2
- IP6K3 | c.450C>G p.L150= | Silent (SNP) | VAF 9/180 reads (5%) | catalogued as COSV53389526; called by muse, mutect2
- KRTAP9-9 | c.381C>G p.L127= | Silent (SNP) | VAF 41/378 reads (11%) | catalogued as COSV67453881; called by muse, varscan2
- MRPL3 | c.219A>G p.L73= | Silent (SNP) | VAF 114/325 reads (35%) | catalogued as COSV53913668; called by muse, mutect2, varscan2
- PCDHA7 | c.276C>G p.R92= | Silent (SNP) | VAF 84/704 reads (12%) | catalogued as rs1554134404, COSV100971634, COSV65342757; called by mutect2, varscan2
- PCDHA9 | c.276C>G p.R92= | Silent (SNP) | VAF 76/162 reads (47%) | catalogued as rs1184191151, COSV65327522; called by muse, varscan2
- PEX12 | c.771C>T p.F257= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as COSV56777743; called by muse, mutect2, varscan2
- SEMA4A | c.876C>G p.L292= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV61772335; called by muse, mutect2, varscan2
- SPTLC2 | c.933C>T p.L311= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV53638906; called by muse, mutect2
- TRIM35 | c.1140C>T p.G380= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs143436239; called by muse, mutect2, varscan2
- UBR4 | c.4386G>A p.V1462= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV64384595; called by muse, mutect2, varscan2
- VN1R4 | c.93C>T p.S31= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV60804783; called by muse, mutect2
- ARIH2 | c.-241C>T | 5'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as rs746188675, COSV62704164; called by mutect2, varscan2
- GCNT2 | c.926-35032dup | Intron (INS) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- ST20-MTHFS | c.-12+480C>T | Intron (SNP) | VAF 10/73 reads (14%) | catalogued as COSV72102881; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472425 G>C | 3'Flank (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
